Somatic mutation profile of tumor specimen MMRF_1854_1_BM_CD138pos (aliquot MMRF_1854_1_BM_CD138pos_T1_KBS5U_L05552) from MMRF case MMRF_1854, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.9 years (19,326 days).
Specimen MMRF_1854_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8184df29-c5c2-48ff-bfd8-a974e65e59a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1854_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1854_1_PB_Whole_C3_KBS5U_L05574; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cf45fdf-49a3-4355-8fc7-3ef77a4d6642

The open-access MAF lists 158 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 39, Silent 23, Intron 12, 5'UTR 7, Nonsense Mutation 7, Splice Site 5, RNA 4, 5'Flank 3, 3'Flank 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 55/410 reads (13%) | catalogued as COSV57861118; called by muse, mutect2, varscan2
- ANKLE2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs200911469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf120 | c.426A>G p.I142M | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs1242757829; called by muse, mutect2, varscan2
- C6orf47 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as rs774374938; called by muse, mutect2, varscan2
- CNTNAP3 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs886759823; called by muse, mutect2
- EIF4A2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV56216525, COSV56218463; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200196531, COSV58558224; called by muse, mutect2, varscan2
- GFUS | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs750059909; called by muse, mutect2, varscan2
- HADHA | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs145798498; called by muse, mutect2, varscan2
- HSD17B13 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100143275; called by muse, mutect2, varscan2
- HTRA4 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | catalogued as rs1318058602; called by muse, mutect2
- INHBB | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as rs766879328, COSV54678601; called by muse, mutect2, varscan2
- NAV2 | c.5507G>A p.R1836H (on ENST00000396087 / NM_001244963.2; = p.R1777H on NM_145117.5) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333833961, COSV60657813; called by muse, mutect2
- NINL | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1014553152, COSV54009424; called by muse, mutect2, varscan2
- NYX | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775575693; called by muse, mutect2, varscan2
- OR2L13 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63547540, COSV63561899; called by muse, mutect2, varscan2
- OR5AK2 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 49/493 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs777949771; called by muse, mutect2, varscan2
- PCDHGB7 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99548107; called by muse, mutect2, varscan2
- PRAG1 | c.2160G>A p.S720= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as rs372835921; called by muse, mutect2, varscan2
- PREX1 | c.1882-1G>T p.X628_splice | Splice Site (SNP) | VAF 34/203 reads (17%) | catalogued as COSV100906585; called by muse, mutect2, varscan2
- RAB3C | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51431623; called by muse, mutect2, varscan2
- RBBP8NL | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs770795292; called by muse, mutect2, varscan2
- RIC8A | c.1111G>T p.E371* (on ENST00000526104 / NM_001286134.1; = p.E377* on NM_021932.5) | Nonsense Mutation (SNP) | VAF 23/181 reads (13%) | catalogued as COSV57344050; called by muse, mutect2, varscan2
- STAG2 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54351706; called by muse, mutect2, varscan2
- THSD7A | c.3137G>A p.R1046H | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs773905875, COSV70259543; called by muse, mutect2, varscan2
- TNFSF13B | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV65516018; called by muse, mutect2, varscan2
- UPK1A | c.732G>A p.T244= | Splice Region (SNP) | VAF 9/69 reads (13%) | catalogued as rs371884359; called by muse, mutect2, varscan2
- ZNF471 | c.1455A>C p.K485N | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100340700; called by muse, mutect2, varscan2
- ADAMTS2 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANHX | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- ARMCX3 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BNC2 | c.2495C>A p.P832H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- C3P1 | n.3314-1G>T | Splice Site (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- CCDC66 | c.2260dup p.R754Kfs*68 (on ENST00000394672 / NM_001353147.1; = p.R720Kfs*68 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 57/169 reads (34%) | called by mutect2, pindel, varscan2
- CD79B | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP44 | c.807del p.A270Lfs*45 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CTNNA2 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFR3B | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.172); called by mutect2, varscan2
- ELP1 | c.1749G>C p.W583C | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2
- ESYT1 | c.2939G>A p.W980* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- EZHIP | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- FAT3 | c.3084G>T p.E1028D | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT3 | c.8005C>A p.L2669M | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- FBN3 | c.7204A>C p.T2402P | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GTF3C1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- HELB | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- HYDIN | c.11160C>G p.N3720K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IGLV3-1 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IPO7 | c.2360T>C p.I787T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAK1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.086); called by muse, mutect2
- ITPK1 | c.671-2A>C p.X224_splice | Splice Site (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- KCNJ16 | c.1020T>G p.S340R | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRA1 | c.585C>A p.Y195* | Nonsense Mutation (SNP) | VAF 29/274 reads (11%) | called by muse, mutect2, varscan2
- MYO10 | c.4732C>G p.Q1578E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCKIPSD | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NHS | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PBX1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR1E | c.733+1G>A p.X245_splice (on ENST00000377792 / NM_001282766.1; = p.X183_splice on NM_022490.4) | Splice Site (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- TEX13C | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TNNT2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TRIP11 | c.4639G>A p.D1547N | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VNN1 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- VPS39 | c.1064A>T p.N355I (on ENST00000348544 / NM_001301138.2; = p.N344I on NM_015289.5) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ZBTB17 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF726 | c.388T>G p.Y130D | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF804B | c.1751T>A p.L584H | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- AADACL4 | c.867C>T p.N289= | Silent (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- CCM2L | c.1597C>T p.L533= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- EML3 | c.366A>G p.E122= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2
- HMCN1 | c.5505G>A p.E1835= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- IGKJ5 | c.28C>T p.L10= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as rs377059806; called by muse, mutect2, varscan2
- INMT | c.453G>A p.P151= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs370569103; called by muse, mutect2, varscan2
- KCNU1 | c.1503G>A p.V501= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- KMT2A | c.285A>T p.S95= | Silent (SNP) | VAF 99/259 reads (38%) | called by muse, mutect2, varscan2
- LRRC72 | c.105G>A p.Q35= | Silent (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- NCAM1 | c.237C>T p.S79= | Silent (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- NRXN2 | c.459C>T p.G153= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99634587; called by muse, mutect2
- OTOG | c.8079G>T p.L2693= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1338C>T p.N446= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1273401894, COSV52021411; called by muse, mutect2, varscan2
- PNPLA4 | c.204G>A p.K68= | Silent (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- PPP6R1 | c.747G>A p.E249= | Silent (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- RAC2 | c.510C>T p.D170= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs752897291; called by muse, mutect2
- REG3A | c.402G>A p.E134= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs775081635; called by muse, mutect2, varscan2
- RPS27A | c.165T>C p.T55= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, varscan2
- SEMA3A | c.1329T>C p.D443= | Silent (SNP) | VAF 16/136 reads (12%) | called by mutect2, varscan2
- SLCO3A1 | c.1908C>T p.F636= | Silent (SNP) | VAF 78/358 reads (22%) | catalogued as rs770075106; called by muse, varscan2
- TECTA | c.1425G>T p.P475= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- TRIM35 | c.675G>A p.K225= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as rs1164684410; called by muse, mutect2, varscan2
- WFIKKN2 | c.795G>T p.V265= | Silent (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- AC008687.1 | c.-132C>T | 5'UTR (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- ACADSB | c.*3676T>C | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- AHRR | c.*3348T>C | 3'UTR (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- AKNA | c.*830T>A | 3'UTR (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+33465A>C | Intron (SNP) | VAF 164/372 reads (44%) | called by muse, mutect2, varscan2
- C1orf21 | c.*9191G>A | 3'UTR (SNP) | VAF 68/128 reads (53%) | catalogued as COSV52407979; called by muse, mutect2, varscan2
- CADM2 | chr3:86068687 G>T | 3'Flank (SNP) | VAF 14/123 reads (11%) | catalogued as rs1018843371; called by muse, mutect2, varscan2
- CCDC78 | chr16:726795 C>T | 5'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- CCNJL | c.*734G>A | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- CELF2 | c.*1251G>A | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- CENPA | c.-56C>T | 5'UTR (SNP) | VAF 11/45 reads (24%) | called by mutect2, varscan2
- CHM | c.315-6152A>T | Intron (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- CLTRN | c.-9C>A | 5'UTR (SNP) | VAF 54/341 reads (16%) | called by muse, mutect2, varscan2
- COL12A1 | c.9181+377A>G | Intron (SNP) | VAF 11/61 reads (18%) | called by mutect2, varscan2
- CREBBP | c.*1482C>T | 3'UTR (SNP) | VAF 14/81 reads (17%) | called by mutect2, varscan2
- DCUN1D3 | c.*1781G>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- DEUP1 | c.790-1889T>G | Intron (SNP) | VAF 239/494 reads (48%) | called by muse, mutect2, varscan2
- DNAJB1P1 | n.355C>T | RNA (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- FAM133A | c.*1307dup | 3'UTR (INS) | VAF 23/51 reads (45%) | called by mutect2, varscan2
- FAM71E2 | c.-103G>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- FARP1 | c.*2335C>T | 3'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as rs933116288; called by muse, mutect2, varscan2
- GATA4 | c.*815G>A | 3'UTR (SNP) | VAF 36/75 reads (48%) | catalogued as rs908966149; called by muse, mutect2, varscan2
- GDA | c.*1113G>T | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- GLA | c.-6G>A | 5'UTR (SNP) | VAF 19/91 reads (21%) | catalogued as rs1462658895; called by muse, mutect2, varscan2
- GOLGA8A | c.*377A>G | 3'UTR (SNP) | VAF 64/170 reads (38%) | called by muse, mutect2
- GOLM1 | c.*899C>T | 3'UTR (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- GPANK1 | c.*119A>G | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- GPC4 | c.*879T>A | 3'UTR (SNP) | VAF 10/56 reads (18%) | catalogued as rs868678365; called by mutect2, varscan2
- GPER1 | c.*318G>A | 3'UTR (SNP) | VAF 46/414 reads (11%) | catalogued as rs1162770840, COSV52470110; called by muse, mutect2, varscan2
- HTR5A | chr7:155068583 G>T | 5'Flank (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863448 G>C | 5'Flank (SNP) | VAF 8/13 reads (62%) | catalogued as rs1566848152; called by muse, varscan2
- IL6 | c.*350del | 3'UTR (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- IRF2 | c.*122T>C | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- KLHL4 | c.*2892T>A | 3'UTR (SNP) | VAF 82/225 reads (36%) | called by muse, mutect2, varscan2
- LPP | c.*12568G>C | 3'UTR (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- MEF2C | chr5:88718622 del G | 3'Flank (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel, varscan2
- MLPH | c.*648G>A | 3'UTR (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- MYEF2 | c.*3300C>T | 3'UTR (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- NAA15 | c.*2373A>G | 3'UTR (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- OTX1 | c.*1175A>G | 3'UTR (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- PABPC1L | c.-23G>A | 5'UTR (SNP) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- PCNX4 | c.689+1623C>A | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- PIK3C2A | c.*1709A>G | 3'UTR (SNP) | VAF 69/146 reads (47%) | called by muse, mutect2, varscan2
- PLCZ1 | c.12-384C>A | Intron (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- PRSS42P | n.1143G>C | RNA (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- PRSS42P | n.1141G>A | RNA (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- RET | c.*579A>T | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- RNF169 | c.*1416del | 3'UTR (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- RPS27A | c.189+42T>C | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, varscan2
- RPS6KA3 | c.-21G>T | 5'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- RYR2 | c.*451G>T | 3'UTR (SNP) | VAF 69/180 reads (38%) | called by muse, mutect2, varscan2
- SHANK1 | c.1223-84C>T | Intron (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- SLC25A36 | c.385+2688A>T | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, varscan2
- SLC35A2 | c.1163+94C>T | Intron (SNP) | VAF 53/122 reads (43%) | catalogued as rs1351578788, COSV54429784; called by muse, mutect2, varscan2
- SLC6A3 | c.928-18C>T | Intron (SNP) | VAF 30/146 reads (21%) | catalogued as rs373449776; called by muse, mutect2, varscan2
- SSTR5-AS1 | n.655C>T | RNA (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- SVIP | c.*2363C>A | 3'UTR (SNP) | VAF 53/235 reads (23%) | called by muse, mutect2, varscan2
- TNRC6B | c.*5563T>G | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- TTC9 | c.*4070G>T | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- TTPA | c.*1121A>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- VAPB | c.*5708T>C | 3'UTR (SNP) | VAF 7/88 reads (8%) | catalogued as rs780996026, COSV55669668; called by muse, mutect2
- VWC2L | c.*1970C>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- XRN1 | c.*549C>G | 3'UTR (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- ZGPAT | c.1051+31A>G | Intron (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*3257_*3258del | 3'UTR (DEL) | VAF 9/84 reads (11%) | called by pindel, varscan2
- ZNF354C | c.*2033T>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ZW10 | c.*383G>A | 3'UTR (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
